Somatic mutation profile of tumor specimen MMRF_2265_1_BM_CD138pos (aliquot MMRF_2265_1_BM_CD138pos_T1_KHS5U_L11229) from MMRF case MMRF_2265, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.3 years (24,594 days).
Specimen MMRF_2265_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ded1ae4e-3238-4b23-886c-7f2d6b32cd80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2265_2_PB_WBC (Blood Derived Normal), aliquot MMRF_2265_2_PB_WBC_C1_KHS5U_L11230; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cb2c557-2c5d-4000-b934-5caeaf562429

The open-access MAF lists 121 somatic variants for this specimen: 51 protein-altering or splice-affecting, 14 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 39, Silent 14, Intron 9, Frame Shift Del 5, 5'UTR 3, RNA 3, Splice Region 2, 3'Flank 2, Nonsense Mutation 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF17 | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs1285187269; called by muse, mutect2
- ATF7IP | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs1267835382; called by muse, mutect2, varscan2
- BAHCC1 | c.1751G>T p.W584L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV57031417; called by muse, mutect2, varscan2
- BCL7B | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as rs376603331; called by muse, mutect2, varscan2
- BLZF1 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 118/229 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs900280942; called by muse, mutect2, varscan2
- CEACAM20 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as rs760795080, COSV57601985; called by muse, mutect2, varscan2
- CSNK1E | c.735C>A p.P245= | Splice Region (SNP) | VAF 10/146 reads (7%) | catalogued as rs777609057; called by muse, mutect2
- DNAH11 | c.5515G>A p.D1839N | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs1415716481, COSV100177182; called by muse, mutect2, varscan2
- ENC1 | c.1185del p.H396Tfs*16 | Frame Shift Del (DEL) | VAF 24/254 reads (9%) | catalogued as COSV56630950; called by mutect2, pindel
- GALNT18 | c.1708C>T p.R570C | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs895518023, COSV104390345; called by muse, mutect2
- HECW2 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs748951495, COSV53659886, COSV99648664; called by muse, mutect2, varscan2
- IGHD6-13 | c.19T>C p.Y7H | Missense Mutation (SNP) | VAF 58/60 reads (97%) | catalogued as rs535576213; called by muse, mutect2, varscan2
- IGHV2-70 | c.304A>C p.T102P | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs373390524; called by muse, varscan2
- IGHV2-70 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 52/58 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs373039668; called by muse, varscan2
- KCNV1 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs1349768376; called by muse, mutect2, varscan2
- MACO1 | c.757del p.R253Efs*18 | Frame Shift Del (DEL) | VAF 43/147 reads (29%) | catalogued as COSV65476861; called by mutect2, pindel, varscan2
- OR2F2 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371292578, COSV101283812; called by muse, mutect2, varscan2
- PHKG1 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51918630; called by muse, mutect2
- RNF148 | c.416T>G p.V139G | Missense Mutation (SNP) | VAF 116/299 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100411513; called by muse, mutect2, varscan2
- SBNO1 | c.1600C>T p.R534* (on ENST00000420886; = p.R533* on NM_018183.5) | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | catalogued as rs867372409; called by muse, varscan2
- SCN5A | c.1186G>T p.V396F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as CM100652, COSV61132781; called by muse, mutect2, varscan2
- SDK1 | c.5527G>A p.A1843T | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.75); PolyPhen probably damaging (1); catalogued as rs1393321136, COSV67369699; called by muse, mutect2, varscan2
- SDK2 | c.2517G>T p.E839D | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV66181087; called by muse, mutect2
- TLN2 | c.4693G>A p.A1565T | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs143603462; called by muse, mutect2, varscan2
- TMC2 | c.35-2A>G p.X12_splice | Splice Site (SNP) | VAF 16/113 reads (14%) | catalogued as rs1471586800; called by muse, mutect2, varscan2
- TRIML2 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 17/347 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.329); catalogued as rs763384722; called by muse, mutect2
- UTP23 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV59124362; called by muse, mutect2
- ZNF317 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs746935577, COSV99927402; called by muse, mutect2, varscan2
- ALDH1A2 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANAPC4 | c.852T>A p.D284E | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- ANKRD30A | c.3718A>C p.S1240R (on ENST00000611781; = p.S1184R on NM_052997.2) | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- AUTS2 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- CDK13 | c.3348T>G p.I1116M | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- DST | c.1943T>C p.I648T (on ENST00000361203 / NM_001374722.1; = p.I322T on NM_001723.6) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- GUCY2F | c.1589dup p.S531Kfs*29 | Frame Shift Ins (INS) | VAF 55/122 reads (45%) | called by mutect2, pindel, varscan2
- KCNT2 | c.1327G>C p.A443P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KLRC2 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- NCAPG | c.736del p.R246Efs*2 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- PLK2 | c.1472G>A p.C491Y | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SALL1 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC63 | c.1053A>G p.E351= | Splice Region (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- SEMA3A | c.118T>G p.L40V | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNNT3 | c.200T>A p.F67Y (on ENST00000397301 / NM_001367846.1; = p.F56Y on NM_006757.4) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAF3 | c.1658_1669del p.T553_I556del | In Frame Del (DEL) | VAF 16/85 reads (19%) | called by mutect2, pindel, varscan2
- UCP2 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UNC5A | c.1085A>T p.H362L | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.013); called by muse, mutect2
- VPS45 | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WAC | c.1232C>A p.P411Q | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZMYND11 | c.898del p.Q300Rfs*38 | Frame Shift Del (DEL) | VAF 25/139 reads (18%) | called by mutect2, pindel, varscan2
- ZNF154 | c.904del p.E302Sfs*172 | Frame Shift Del (DEL) | VAF 44/330 reads (13%) | called by pindel, varscan2
- ZNF79 | c.341T>G p.I114R | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.029); called by muse, varscan2
- ADCY6 | c.1140C>T p.I380= | Silent (SNP) | VAF 26/251 reads (10%) | called by muse, mutect2, varscan2
- ANKRD28 | c.2268A>G p.G756= | Silent (SNP) | VAF 9/63 reads (14%) | called by muse, varscan2
- ATP6V1C2 | c.600C>T p.Y200= | Silent (SNP) | VAF 105/234 reads (45%) | catalogued as rs201583924; called by muse, mutect2, varscan2
- DIAPH3 | c.861T>C p.D287= (on ENST00000400324 / NM_001042517.2; = p.D24= on NM_030932.3) | Silent (SNP) | VAF 40/74 reads (54%) | called by muse, mutect2, varscan2
- ELOVL1 | c.90A>C p.L30= | Silent (SNP) | VAF 9/150 reads (6%) | called by muse, mutect2
- IGLV3-1 | c.201T>C p.Y67= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as rs559956832; called by muse, mutect2, varscan2
- KANK1 | c.3489C>T p.N1163= | Silent (SNP) | VAF 26/436 reads (6%) | called by muse, mutect2
- LRP1B | c.11679T>A p.A3893= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2
- NELL1 | c.903C>T p.A301= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as rs746083104; called by muse, mutect2
- NINL | c.1950G>A p.L650= | Silent (SNP) | VAF 66/152 reads (43%) | catalogued as rs1269575065; called by muse, mutect2, varscan2
- PGAP4 | c.435C>T p.N145= | Silent (SNP) | VAF 50/457 reads (11%) | catalogued as rs1384006957; called by muse, mutect2, varscan2
- PKHD1 | c.10743C>G p.L3581= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as rs770308751, COSV64381591, COSV64386144; called by muse, mutect2, varscan2
- SLC7A6 | c.177C>T p.I59= | Silent (SNP) | VAF 93/234 reads (40%) | catalogued as rs147251962; called by muse, mutect2, varscan2
- TNXB | c.4656G>T p.V1552= (on ENST00000647633; = p.V1305= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- AC006059.2 | c.*372C>T | 3'UTR (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- AGAP1 | c.*1568C>T | 3'UTR (SNP) | VAF 4/44 reads (9%) | catalogued as rs1384197567; called by muse, mutect2
- AMMECR1 | c.*247T>G | 3'UTR (SNP) | VAF 22/55 reads (40%) | catalogued as rs764554903; called by muse, mutect2, varscan2
- BMP3 | c.*3205G>A | 3'UTR (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- BRPF3 | c.*718C>A | 3'UTR (SNP) | VAF 153/352 reads (43%) | called by muse, mutect2, varscan2
- C11orf40 | n.65A>G | RNA (SNP) | VAF 22/60 reads (37%) | catalogued as COSV56890009; called by muse, mutect2, varscan2
- CAPRIN1 | c.*331G>C | 3'UTR (SNP) | VAF 33/224 reads (15%) | called by muse, mutect2, varscan2
- CCDC149 | c.*1905del | 3'UTR (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- CD93 | c.*494C>A | 3'UTR (SNP) | VAF 35/103 reads (34%) | called by muse, mutect2, varscan2
- CDHR1 | c.*712G>A | 3'UTR (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- CLEC12B | c.680+739G>A | Intron (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- CPLX3 | c.*1249G>A | 3'UTR (SNP) | VAF 129/217 reads (59%) | catalogued as rs1053584765; called by muse, mutect2, varscan2
- CRISPLD2 | c.*742C>A | 3'UTR (SNP) | VAF 66/154 reads (43%) | called by muse, mutect2, varscan2
- DCHS2 | n.3642G>C | RNA (SNP) | VAF 64/147 reads (44%) | called by muse, mutect2, varscan2
- DCX | c.*7587G>A | 3'UTR (SNP) | VAF 35/108 reads (32%) | called by muse, mutect2, varscan2
- DMD | c.*428G>A | 3'UTR (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- DNAJC21 | c.-149G>A | 5'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- DNER | c.*381C>T | 3'UTR (SNP) | VAF 8/92 reads (9%) | catalogued as rs925984588; called by muse, mutect2
- EPHX2 | c.*9G>A | 3'UTR (SNP) | VAF 6/44 reads (14%) | catalogued as rs369372219; called by muse, mutect2, varscan2
- EYA1 | c.-54-101A>C | Intron (SNP) | VAF 50/110 reads (45%) | called by muse, mutect2, varscan2
- FOXJ3 | c.*189C>G | 3'UTR (SNP) | VAF 4/65 reads (6%) | called by muse, mutect2
- FSHB | c.*124T>A | 3'UTR (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2, varscan2
- GRPEL2 | c.*384T>C | 3'UTR (SNP) | VAF 52/125 reads (42%) | called by muse, mutect2, varscan2
- HAP1 | chr17:41721567 del TTTTC | 3'Flank (DEL) | VAF 29/88 reads (33%) | called by pindel, varscan2
- HRH1 | c.*2550G>A | 3'UTR (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- HUWE1 | c.*375dup | 3'UTR (INS) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- IL17RA | c.*4172C>G | 3'UTR (SNP) | VAF 34/88 reads (39%) | catalogued as rs189600087; called by muse, mutect2
- INS-IGF2 | c.407+46T>C | Intron (SNP) | VAF 6/70 reads (9%) | catalogued as rs1268561719; called by muse, mutect2
- KAZN | c.*653C>T | 3'UTR (SNP) | VAF 66/164 reads (40%) | called by muse, mutect2, varscan2
- KCNIP3 | c.-85A>T | 5'UTR (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- KCNJ5 | chr11:128917219 C>T | 3'Flank (SNP) | VAF 23/180 reads (13%) | called by muse, mutect2, varscan2
- LASP1 | c.*2695A>G | 3'UTR (SNP) | VAF 5/143 reads (3%) | called by muse, mutect2
- LMX1A | c.*1134C>A | 3'UTR (SNP) | VAF 74/149 reads (50%) | catalogued as rs1320421123; called by muse, mutect2, varscan2
- LRRC2 | c.*136del | 3'UTR (DEL) | VAF 36/93 reads (39%) | called by mutect2, varscan2
- MCTS1 | c.11+501C>T | Intron (SNP) | VAF 35/154 reads (23%) | called by muse, mutect2, varscan2
- MIR663B | n.53T>G | RNA (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- MPP2 | c.*1353C>G | 3'UTR (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- NFYB | c.*214A>G | 3'UTR (SNP) | VAF 14/89 reads (16%) | catalogued as COSV99527242; called by muse, mutect2, varscan2
- NPY1R | c.*673C>A | 3'UTR (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- PGLS | c.289-34A>C | Intron (SNP) | VAF 14/139 reads (10%) | called by muse, mutect2
- PRR16 | c.*448A>C | 3'UTR (SNP) | VAF 22/63 reads (35%) | catalogued as rs1266078954; called by muse, mutect2, varscan2
- RBL1 | c.-3G>C | 5'UTR (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- RFX5 | c.*1247A>T | 3'UTR (SNP) | VAF 58/140 reads (41%) | called by muse, mutect2, varscan2
- RGP1 | c.*2762C>T | 3'UTR (SNP) | VAF 14/42 reads (33%) | catalogued as rs185397831; called by muse, mutect2, varscan2
- RPS14 | c.-2-60G>T | Intron (SNP) | VAF 83/259 reads (32%) | called by muse, mutect2, varscan2
- SAR1A | c.348+58del | Intron (DEL) | VAF 43/258 reads (17%) | catalogued as rs746219422; called by pindel, varscan2
- SHROOM4 | c.*997+1386G>A | Intron (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- SLC23A2 | c.*2725G>A | 3'UTR (SNP) | VAF 13/119 reads (11%) | catalogued as rs893888309; called by muse, mutect2, varscan2
- SLC9A7 | c.*1505A>G | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- SON | c.6768+110T>C | Intron (SNP) | VAF 12/179 reads (7%) | called by muse, mutect2
- ST3GAL2 | c.*2198C>T | 3'UTR (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- SV2B | c.*252G>A | 3'UTR (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- TKFC | c.*1325G>A | 3'UTR (SNP) | VAF 32/165 reads (19%) | called by muse, mutect2, varscan2
- TMX4 | c.*1563C>G | 3'UTR (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- TSPEAR | c.*106G>A | 3'UTR (SNP) | VAF 16/60 reads (27%) | catalogued as rs1261585477; called by muse, mutect2, varscan2
- USP37 | c.*2669G>A | 3'UTR (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
